Gene-level copy-number profile of tumor specimen TCGA-CV-7413-01A from TCGA case TCGA-CV-7413, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 74.6 years (27,231 days).
Specimen TCGA-CV-7413-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.fde351ce-fd63-4ed4-93c0-c1bde3747932.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-7413-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1c622b13-f9c5-441f-831e-9e4b3b1a4f30

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 41; copy number 1: 1; copy number 2: 11,633; copy number 3: 219; copy number 4: 42,241; copy number 5: 316; copy number 6: 4,425; copy number 7: 805; copy number 12: 109; copy number 16: 30.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-7413-01A-11D-2077-01): tumor purity 0.44, ploidy 1.86, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 41 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:26,614,261–30,694,142, 40 genes (within-gene range 0–2): AC099754.1, LRRC3B, NEK10, MICOS10P3, RNU6-342P, AC099535.2, SLC4A7, RPS20P15, AC099535.1, RNU1-96P, AC137675.1, Y_RNA, AC098614.1, AC098614.2, KIAA1143P2, LINC02084, EOMES, LINC01980, LINC01981, LINC01967, CMC1, AZI2, ZCWPW2, AC098650.1, FAM96AP1, AC093142.1, RBMS3, RBMS3-AS3, MESTP4, RPS12P5, RBMS3-AS2, MTND4LP9, RBMS3-AS1, AC025614.2, AC025614.1, U3, LINC01985, AC116035.1, TGFBR2, AC096921.1.
- chr3:59,809,269–59,811,310, 1 gene: AC093418.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 139 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:19,036,282–21,451,463, 139 genes, copy number 12–16 (within-gene range 4–16) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
